Somatic mutation profile of tumor specimen TCGA-DU-5874-01A (aliquot TCGA-DU-5874-01A-11D-1705-08) from TCGA case TCGA-DU-5874, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 62.6 years (22,847 days).
Specimen TCGA-DU-5874-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 379ea319-00c0-4782-b305-b705ab4e7ca5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5874-10A (Blood Derived Normal), aliquot TCGA-DU-5874-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2264f128-737a-4117-a468-4139c77c6541

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, Nonsense Mutation 2, Translation Start Site 1, Frame Shift Del 1, Splice Site 1, 5'Flank 1, Intron 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP26B1 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281875231, CM119271, COSV50010732; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- LZTR1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587777180, CM140928, COSV53145166; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP10D | c.1649T>C p.V550A | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.241); catalogued as COSV56703859; called by muse, mutect2, varscan2
- ATP2B3 | c.3508C>T p.R1170C | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.209); catalogued as rs368530977, COSV54840353; called by muse, mutect2, varscan2
- CD93 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs752043162, COSV55663201; called by muse, mutect2, varscan2
- CHMP4B | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.842); catalogued as COSV54135035; called by muse, mutect2
- CUL7 | c.3448G>A p.V1150M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs753135540, COSV54813055; called by muse, mutect2, varscan2
- FBLN1 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53043706; called by muse, mutect2, varscan2
- GABRE | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs1410904417, COSV64818869; called by muse, mutect2, varscan2
- GLIS3 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV67941240; called by muse, mutect2, varscan2
- HCCS | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs1413276234, COSV58238791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEPACAM2 | c.1227C>A p.F409L (on ENST00000394468 / NM_001039372.4; = p.F397L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59057794, COSV59059008; called by muse, mutect2, varscan2
- LRRK1 | c.1562T>G p.I521S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.196); catalogued as COSV52601859; called by muse, mutect2, varscan2
- MUC5AC | c.14767G>A p.G4923S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.96); catalogued as rs772605646, COSV100611379, COSV100611631; called by muse, mutect2, varscan2
- MYH6 | c.4780C>T p.R1594W | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs545198745, COSV62447886, COSV62447912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPVF | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV56060125; called by muse, mutect2, varscan2
- OR11G2 | c.817A>T p.R273* | Nonsense Mutation (SNP) | VAF 11/169 reads (7%) | catalogued as COSV62131763; called by muse, mutect2
- OR1C1 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563143111, COSV68715361; called by muse, mutect2, varscan2
- PPP1R42 | c.448A>T p.I150L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV61206605; called by muse, mutect2, varscan2
- PTGES2 | c.887+1G>A p.X296_splice | Splice Site (SNP) | VAF 18/43 reads (42%) | catalogued as COSV52968000; called by muse, mutect2, varscan2
- PTPN21 | c.2866A>G p.I956V | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV60845753; called by muse, mutect2, varscan2
- PUM3 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs758633890, COSV67395685, COSV67396654; called by muse, mutect2, varscan2
- SH2D2A | c.86T>C p.M29T | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1182852232, COSV63884334; called by muse, mutect2, varscan2
- SIPA1L2 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV53383541; called by muse, mutect2
- SLC6A19 | c.1030del p.L344Sfs*12 | Frame Shift Del (DEL) | VAF 45/122 reads (37%) | catalogued as rs748490870, COSV58671818; called by mutect2, pindel
- SLC6A6 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs1375781532, COSV62647583; called by muse, mutect2, varscan2
- SLFN12 | c.555dup p.D186* | Frame Shift Ins (INS) | VAF 24/90 reads (27%) | catalogued as rs747319777; called by mutect2, varscan2
- SON | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs781309621, COSV51650596; called by muse, mutect2, varscan2
- USH1G | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.062); catalogued as COSV58880606; called by muse, mutect2, varscan2
- WIPI2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1288690829, COSV56587051; called by muse, mutect2, varscan2
- ZMYM6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV58183573; called by muse, mutect2, varscan2
- AIFM2 | c.456G>A p.S152= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as rs556198278, COSV57158580; called by muse, mutect2, varscan2
- FGF14 | c.81G>A p.R27= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs1309195990, COSV65935941; called by muse, mutect2, varscan2
- FSTL3 | c.594G>A p.A198= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1568203711, COSV51261402, COSV99383873; called by muse, mutect2, varscan2
- INAVA | c.1386C>T p.S462= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as COSV66255871; called by muse, mutect2, varscan2
- JADE2 | c.2277C>T p.S759= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs377702719, COSV50911605; called by muse, mutect2, varscan2
- MYO9A | c.6876A>G p.P2292= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as COSV61847621; called by muse, mutect2, varscan2
- NTF3 | c.274C>T p.L92= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV58417164; called by muse, mutect2, varscan2
- PA2G4 | c.687C>T p.L229= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs761782091, COSV57567441; called by muse, mutect2, varscan2
- PITX1 | c.555C>T p.A185= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs761995125, COSV54761527; called by muse, mutect2, varscan2
- PPP4R1 | c.2640C>T p.N880= (on ENST00000400556 / NM_001042388.3; = p.N863= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 65/132 reads (49%) | catalogued as rs761567359, COSV53280363; called by muse, mutect2, varscan2
- SLC35G6 | c.96G>A p.Q32= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV59489201; called by muse, mutect2, varscan2
- ADGRA1 | chr10:133084991 T>C | 5'Flank (SNP) | VAF 50/127 reads (39%) | catalogued as COSV63416412; called by muse, mutect2, varscan2
- DDIT3 | c.-81+1214A>T | Intron (SNP) | VAF 24/47 reads (51%) | catalogued as COSV100007196; called by muse, mutect2
- SNORD116-4 | n.44C>G | RNA (SNP) | VAF 48/127 reads (38%) | called by muse, mutect2, varscan2
